Somatic mutation profile of tumor specimen TCGA-B0-5084-01A (aliquot TCGA-B0-5084-01A-01D-1462-08) from TCGA case TCGA-B0-5084, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 33.5 years (12,219 days).
Specimen TCGA-B0-5084-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bc27b30-263c-4c4a-82e8-58f838f2ee88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5084-11A (Solid Tissue Normal), aliquot TCGA-B0-5084-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d60ba95-f697-4c70-948c-cd40946c026d

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 32, Silent 9, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP11 | c.4130A>C p.K1377T | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV50298037; called by muse, mutect2, varscan2
- ANKRD34A | c.1004G>C p.R335P | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.701); catalogued as COSV60161270; called by muse, mutect2, varscan2
- C7 | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200879856, COSV57475229; called by muse, mutect2, varscan2
- CAPN10 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867854825, COSV54377409; called by muse, mutect2, varscan2
- CAPN2 | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54337300; called by muse, mutect2, varscan2
- COG3 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.168); catalogued as COSV63073661; called by muse, mutect2, varscan2
- EIF3E | c.18G>T p.L6F | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55203932; called by muse, mutect2, varscan2
- EZH1 | c.1243G>T p.A415S | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV70549879; called by muse, mutect2, varscan2
- FAM161B | c.1562C>T p.A521V (on ENST00000651776; = p.A458V on NM_152445.3) | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV54102925; called by muse, mutect2, varscan2
- FER | c.1614C>G p.I538M | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55295482; called by muse, mutect2, varscan2
- ILDR2 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.072); catalogued as COSV54832417; called by muse, varscan2
- IRX1 | c.584C>A p.A195E | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV57358294, COSV57358664; called by muse, mutect2, varscan2
- KCNH8 | c.2199G>T p.R733S | Missense Mutation (SNP) | VAF 54/78 reads (69%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV60468131; called by muse, mutect2, varscan2
- LMTK2 | c.4441T>C p.F1481L | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs1050569099, COSV51998544; called by muse, mutect2, varscan2
- MFSD14B | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64701183; called by muse, mutect2, varscan2
- NF2 | c.363+2T>G p.X121_splice | Splice Site (SNP) | VAF 110/132 reads (83%) | catalogued as COSV58525672; called by muse, mutect2, varscan2
- NMT1 | c.310G>C p.G104R | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV51960234, COSV51960641; called by muse, mutect2, varscan2
- NOTCH1 | c.3631C>T p.R1211W | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766644919, COSV53063996; ClinVar: not provided; called by muse, mutect2, varscan2
- OAS2 | c.1983G>T p.K661N | Missense Mutation (SNP) | VAF 168/459 reads (37%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.773); catalogued as rs1429377709, COSV60803133; called by muse, mutect2, varscan2
- OCM | c.62-2A>T p.X21_splice | Splice Site (SNP) | VAF 78/266 reads (29%) | catalogued as COSV54194635; called by muse, mutect2, varscan2
- OTOL1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753710700, COSV60007256; called by muse, mutect2, varscan2
- SAFB | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 57/94 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs753148563, COSV52651136; called by muse, mutect2, varscan2
- SLC30A1 | c.893T>A p.I298N | Missense Mutation (SNP) | VAF 133/345 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV65361296; called by muse, mutect2, varscan2
- SPG21 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs777968793, COSV52603139; called by muse, mutect2, varscan2
- TAB1 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs748782092, COSV53372001; called by muse, mutect2, varscan2
- TACC2 | c.2347dup p.Q783Pfs*45 | Frame Shift Ins (INS) | VAF 38/124 reads (31%) | catalogued as rs750901207; called by mutect2, varscan2
- TBC1D5 | c.1848T>G p.H616Q | Missense Mutation (SNP) | VAF 109/134 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs754764435, COSV53761763; called by muse, mutect2, varscan2
- TMCO3 | c.281A>G p.H94R | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.093); catalogued as COSV100952294; called by muse, mutect2, varscan2
- TMCO3 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV100952296; called by muse, mutect2, varscan2
- USP37 | c.2396A>G p.Q799R | Missense Mutation (SNP) | VAF 109/259 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1329917992, COSV51444653; called by muse, mutect2, varscan2
- XK | c.324A>C p.Q108H | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV66120390; called by muse, mutect2, varscan2
- ZNF257 | c.858A>T p.K286N | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV71309688; called by muse, mutect2, varscan2
- ZNF451 | c.2067C>A p.H689Q | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV62598244; called by muse, mutect2, varscan2
- ZNF460 | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64415884; called by muse, mutect2, varscan2
- BIN2 | c.534_537del p.N178Kfs*9 | Frame Shift Del (DEL) | VAF 60/155 reads (39%) | called by mutect2, pindel, varscan2
- IGLC2 | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NSD1 | c.1753del p.S585Qfs*14 | Frame Shift Del (DEL) | VAF 90/156 reads (58%) | called by mutect2, pindel, varscan2
- ZNF430 | c.712dup p.C238Lfs*3 | Frame Shift Ins (INS) | VAF 74/180 reads (41%) | called by mutect2, pindel, varscan2
- ALPG | c.1236C>T p.Y412= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs563231782, COSV99779216; called by muse, mutect2, varscan2
- ALPP | c.1245C>T p.Y415= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs752955692, COSV67396201, COSV67396216; called by mutect2, varscan2
- ATP5F1B | c.736T>C p.L246= | Silent (SNP) | VAF 80/255 reads (31%) | catalogued as COSV56261388; called by muse, mutect2, varscan2
- DLL1 | c.1356C>T p.C452= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs148319460; called by muse, mutect2, varscan2
- DOCK4 | c.4437G>A p.K1479= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV70239263; called by muse, mutect2, varscan2
- MGAM | c.1650T>C p.N550= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV72074964; called by muse, mutect2, varscan2
- PCDHA4 | c.1869C>T p.R623= | Silent (SNP) | VAF 51/119 reads (43%) | catalogued as rs782158159, COSV63543046; called by muse, mutect2, varscan2
- RFC2 | c.372T>C p.A124= | Silent (SNP) | VAF 87/241 reads (36%) | catalogued as COSV50016398; called by muse, mutect2, varscan2
- ZNF606 | c.1185T>G p.T395= | Silent (SNP) | VAF 83/123 reads (67%) | catalogued as COSV58706490; called by muse, mutect2, varscan2
